Somatic mutation profile of tumor specimen MMRF_2074_1_BM_CD138pos (aliquot MMRF_2074_1_BM_CD138pos_T1_KHS5U_L08094) from MMRF case MMRF_2074, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,388 days).
Specimen MMRF_2074_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 994cb031-d94f-4d17-b8c5-5b728ae3feb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2074_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2074_1_PB_Whole_C2_KHS5U_L08095; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93a4c7f1-07e0-45ee-94f4-74d6cbc07c63

The open-access MAF lists 79 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 20, Silent 12, Intron 10, Nonsense Mutation 4, 5'UTR 2, RNA 2, 5'Flank 2, 3'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 46/125 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ARFGEF3 | c.3420T>G p.F1140L | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1056565120; called by muse, mutect2
- CHRDL1 | c.160G>A p.V54I (on ENST00000372045; = p.V60I on NM_145234.4) | Missense Mutation (SNP) | VAF 61/61 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs781745771, COSV54327616; called by muse, mutect2, varscan2
- CHRM1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1265053742, COSV100186322; called by muse, mutect2, varscan2
- IGHD3-16 | c.12A>T p.L4F | Missense Mutation (SNP) | VAF 37/41 reads (90%) | catalogued as rs782520724; called by muse, mutect2, varscan2
- IGKJ4 | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 62/78 reads (79%) | PolyPhen benign (0.042); catalogued as rs180910647; called by muse, varscan2
- IGKV3-20 | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs568419040; called by muse, mutect2, varscan2
- OR8K3 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs766060464, COSV57130713, COSV57130774; called by muse, mutect2, varscan2
- PAK6 | c.365G>A p.W122* | Nonsense Mutation (SNP) | VAF 89/375 reads (24%) | catalogued as rs1009036281; called by muse, mutect2, varscan2
- PLD3 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735037; called by muse, mutect2, varscan2
- TPTE | c.806G>A p.R269Q (on ENST00000618007 / NM_199261.4; = p.R251Q on NM_199259.4) | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.389); catalogued as rs754178012; called by muse, mutect2, varscan2
- TRPM8 | c.3264G>T p.K1088N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs774813350; called by muse, varscan2
- ZSCAN1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV56602231; called by muse, mutect2, varscan2
- ADGRV1 | c.4205C>T p.T1402I | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ADGRV1 | c.10204C>T p.L3402F | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BMPER | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHRNA1 | c.820A>C p.T274P (on ENST00000261007 / NM_001039523.3; = p.T249P on NM_000079.4) | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by mutect2, varscan2
- CNOT1 | c.2261T>A p.F754Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- COL14A1 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GATA2 | c.780C>G p.Y260* | Nonsense Mutation (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- HNRNPM | c.1916G>A p.G639D | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HSPA5 | c.1825C>G p.Q609E | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PARP14 | c.4674T>G p.D1558E | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PAX9 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2
- SLC15A2 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 48/203 reads (24%) | called by muse, mutect2, varscan2
- STAT3 | c.1472del p.N491Tfs*18 | Frame Shift Del (DEL) | VAF 11/127 reads (9%) | called by mutect2, pindel
- TRMT6 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC39B | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- ZNF235 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.63C>G p.V21= | Silent (SNP) | VAF 32/36 reads (89%) | called by muse, varscan2
- IGHV2-70 | c.9A>T p.I3= | Silent (SNP) | VAF 12/12 reads (100%) | catalogued as rs61734098; called by mutect2, varscan2
- KRT84 | c.1299C>A p.A433= | Silent (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- LCN8 | c.312C>T p.H104= (on ENST00000612714 / NM_001345934.1; = p.H81= on NM_178469.3) | Silent (SNP) | VAF 73/222 reads (33%) | catalogued as rs145380406; called by muse, mutect2, varscan2
- PCDHA11 | c.2226C>T p.R742= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs1164407502, COSV56501936; called by muse, mutect2, varscan2
- PITPNM3 | c.27T>C p.G9= | Silent (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- PPP1R9A | c.1008C>T p.I336= | Silent (SNP) | VAF 65/222 reads (29%) | catalogued as COSV56895609; called by muse, mutect2, varscan2
- PRPF18 | c.666C>T p.T222= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs759609274; called by muse, mutect2, varscan2
- RELCH | c.2466T>G p.G822= | Silent (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- SPPL2A | c.1500T>C p.H500= | Silent (SNP) | VAF 222/447 reads (50%) | called by muse, mutect2, varscan2
- TLN2 | c.2403C>T p.Y801= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as rs367832806; called by muse, mutect2, varscan2
- UBR1 | c.1449G>A p.L483= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- ADAMDEC1 | c.*162T>C | 3'UTR (SNP) | VAF 134/139 reads (96%) | called by muse, mutect2, varscan2
- ADGRE4P | n.1920G>A | RNA (SNP) | VAF 68/207 reads (33%) | catalogued as rs758966752; called by muse, mutect2, varscan2
- AKR1E2 | c.-46T>A | 5'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2
- BICD2 | c.2469+222C>T | Intron (SNP) | VAF 39/110 reads (35%) | catalogued as rs1347723303; called by muse, mutect2, varscan2
- C21orf91 | c.*203G>A | 3'UTR (SNP) | VAF 67/148 reads (45%) | called by muse, mutect2, varscan2
- CALML3-AS1 | n.2536_2539del | RNA (DEL) | VAF 45/118 reads (38%) | called by pindel, varscan2
- CAV1 | c.*655G>T | 3'UTR (SNP) | VAF 6/139 reads (4%) | called by muse, mutect2
- CLN8 | c.*5516A>G | 3'UTR (SNP) | VAF 28/65 reads (43%) | catalogued as rs757509782; called by muse, mutect2, varscan2
- COL25A1 | c.1657-62G>T | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2
- EIF4A2 | c.1079+295T>A | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- EIF4A2 | c.1079+391T>C | Intron (SNP) | VAF 50/174 reads (29%) | called by muse, mutect2
- EXOC5 | c.*4029G>A | 3'UTR (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- F13A1 | c.1113-9118del | Intron (DEL) | VAF 286/585 reads (49%) | catalogued as rs1429170211; called by mutect2, pindel, varscan2
- INHBC | c.*343A>G | 3'UTR (SNP) | VAF 124/297 reads (42%) | catalogued as rs1033352012; called by muse, mutect2, varscan2
- INPP4B | c.2643-912T>C | Intron (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.*441G>C | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- KIF1A | c.*2827del | 3'UTR (DEL) | VAF 60/176 reads (34%) | called by mutect2, pindel, varscan2
- KIF26A | chr14:104179854 C>T | 3'Flank (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- LOXL1 | c.-150G>A | 5'UTR (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- LTB | c.163-141G>C | Intron (SNP) | VAF 200/349 reads (57%) | catalogued as rs4647180; called by muse, mutect2, varscan2
- MAPK8IP1 | c.*659G>A | 3'UTR (SNP) | VAF 83/120 reads (69%) | called by muse, mutect2, varscan2
- MARCHF1 | c.*3888C>T | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- MBD3 | c.*2970G>C | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- MCL1 | c.*380A>C | 3'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- MIR5195 | chr14:106851235 T>A | 5'Flank (SNP) | VAF 82/168 reads (49%) | catalogued as rs561199976; called by muse, mutect2, varscan2
- MTERF1 | c.*1772G>C | 3'UTR (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- OR7G2 | chr19:9102210 del AAAC | 3'Flank (DEL) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- PDZD3 | c.1485+65C>T | Intron (SNP) | VAF 29/571 reads (5%) | catalogued as rs908401326; called by muse, mutect2
- PHKB | c.2427+121G>A | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- PNISR | c.*1104T>C | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- PRCP | chr11:82900816 C>A | 5'Flank (SNP) | VAF 92/350 reads (26%) | called by muse, varscan2
- RGP1 | c.*5063A>C | 3'UTR (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- SLC23A3 | c.798+53G>A | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- SLCO2B1 | c.*1627del | 3'UTR (DEL) | VAF 22/98 reads (22%) | catalogued as rs891861874; called by mutect2, pindel, varscan2
- TOR1AIP2 | c.*6012C>T | 3'UTR (SNP) | VAF 83/140 reads (59%) | called by muse, mutect2, varscan2
- TRAM2 | c.*679T>C | 3'UTR (SNP) | VAF 47/206 reads (23%) | catalogued as rs997449322; called by muse, mutect2, varscan2
- ZNF709 | c.*1105A>G | 3'UTR (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- ZNF716 | c.*1909dup | 3'UTR (INS) | VAF 10/28 reads (36%) | called by mutect2, varscan2
